Somatic mutation profile of tumor specimen MBCProject_5856_T0A_WES (aliquot MBCProject_5856_T0A_WES_1) from CMI case MBCProject_5856, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 60.0 years (21,902 days).
Specimen MBCProject_5856_T0A_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84a612c7-e27f-4426-8737-c637019f7e6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5856_SALIVA (Saliva), aliquot MBCProject_5856_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/112edb84-aa8b-4bae-9915-4f70317d1175

The open-access MAF lists 29 somatic variants for this specimen: 14 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 8, Intron 3, 3'UTR 2, 5'Flank 1, Frame Shift Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM7 | c.1837G>C p.G613R | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as rs778041314, COSV51539239; called by muse, mutect2, varscan2
- CCDC197 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs748749118, COSV58939316; called by muse, mutect2, varscan2
- CNTNAP3B | c.2069C>G p.P690R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1198586876; called by muse, varscan2
- GDPD4 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 479/1225 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.534); catalogued as rs1210817231, COSV60017262; called by muse, mutect2, varscan2
- GOT1L1 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.027); catalogued as rs1408567571; called by muse, mutect2, varscan2
- OLIG2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV100324383, COSV60973530; called by muse, mutect2, varscan2
- PRLH | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs770338709; called by muse, mutect2, varscan2
- GDPD4 | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 212/516 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LTK | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PCDHGB2 | c.1219del p.D407Tfs*30 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- PXDNL | c.1526-6_1538del p.X509_splice | Splice Site (DEL) | VAF 16/66 reads (24%) | called by mutect2, pindel
- SOX6 | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SPHKAP | c.3396C>A p.F1132L | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TNIP2 | c.1156C>A p.P386T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, varscan2
- ARHGAP10 | c.1455C>T p.S485= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs372408519; called by muse, mutect2, varscan2
- CTNS | c.39C>G p.P13= | Silent (SNP) | VAF 81/133 reads (61%) | called by muse, mutect2, varscan2
- KIAA1755 | c.1104G>A p.P368= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs371997422, COSV54073610; called by muse, mutect2, varscan2
- PTER | c.645A>T p.I215= | Silent (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- RHCE | c.132C>T p.L44= | Silent (SNP) | VAF 54/139 reads (39%) | catalogued as rs768223782, COSV99604050; called by muse, mutect2, varscan2
- RHD | c.132C>T p.L44= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs769626782; called by mutect2, varscan2
- SYNJ1 | c.1137G>A p.K379= | Silent (SNP) | VAF 32/196 reads (16%) | called by muse, varscan2
- ZNF726 | c.1719G>A p.A573= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as rs770183581, COSV58043956; called by muse, mutect2, varscan2
- AOX3P | chr2:200676927 T>C | 5'Flank (SNP) | VAF 69/143 reads (48%) | called by muse, mutect2, varscan2
- CHD5 | c.*119_*127delinsAAAAAAAAA | 3'UTR (ONP) | VAF 6/40 reads (15%) | called by mutect2*, pindel
- DOCK11 | c.3292+499dup | Intron (INS) | VAF 29/105 reads (28%) | called by mutect2, varscan2
- ENPEP | c.1510-912G>T | Intron (SNP) | VAF 53/137 reads (39%) | catalogued as rs1001340490; called by muse, mutect2, varscan2
- LGALS2 | c.*1_*2dup | 3'UTR (INS) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- PTENP1 | n.1081C>T | RNA (SNP) | VAF 50/148 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.34264+5686G>T | Intron (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
